Surgical pathology report (de-identified scan), TCGA case TCGA-06-6389, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6389-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

CLINICAL HISTORY

Brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Temporal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, temporal lobe tumor, excision biopsy: **Anaplastic astrocytoma (WHO Grade III)** (see comment).

COMMENT

Sections show a poorly preserved gemistocytic astrocytoma demonstrating moderately high pleomorphism. A few scattered mitotic figures and apoptotic bodies are noted. Microvascular proliferation and necrosis are not seen. A minor oligodendroglial component may also be present. The tumor is diffusely and strongly p53 positive. The Ki-67 labeling index is approximately 20%. Positive and negative controls show appropriate immunoreactivity.

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is NOT detected.

Informative loci are: D1S1592, D1S552, D19S219, D19S412, and PLA2G4C

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

DNA extracted from a corresponding blood specimen was used as normal reference control.

[page 2 of 4]
H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as

backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the

first line markers at that chromosome arm are uninformative or otherwise

ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p

and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a

stand-alone diagnostic test. This test was developed and its performance

characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample

may preclude the detection of allelic loss.

Electronically Signed Out
[REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

H slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

[page 3 of 4]
MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Addendum Diagnosis

*****Note Diagnosis Modified*****

A. Brain, temporal lobe tumor, excision: Glioblastoma (WHO Grade IV) (see comment).

Addendum Comment

Examination of H stained slides from the [REDACTED] for this patient shows the presence of greater pleomorphism and focal microvascular proliferation in the sections from "vial 1 top and vial 1 bottom." The presence of these features upgrades the diagnosis from a WHO grade III to a WHO grade IV glioma, i.e., glioblastoma.

Electronically Signed Out

[page 4 of 4]
[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, temporal tumor, excision biopsy: High-grade astrocytoma.
Frozen
section and smears performed at [REDACTED] and results
reported to
the Physician of Record. [REDACTED]

[REDACTED]

ICD-9(s):
191.9 191.9

[REDACTED]

Histo Data

Part A: Temporal tumor, excision biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
LOH-curls x 1	1	[REDACTED]	
MGMT-curls x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
P53DO7 x 1	1	[REDACTED]	
Rct 1 H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
Rct 1 H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
Rct 1 H/E x 1	3	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file 9043c1ff-2a5a-4071-a673-a81e4f71b378 (TCGA-06-6389.8CA0AE5B-4448-4F8B-8CDC-50E6209CED26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).